Somatic mutation profile of tumor specimen ALCH-B3AX-TTP1-A (aliquot ALCH-B3AX-TTP1-A-1-0-D-A80C-36) from ALCHEMIST case ALCH-B3AX, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 50.3 years (18,362 days).
Specimen ALCH-B3AX-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3dce5aa3-e9c0-4ea1-986a-31c609f28e5c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3AX-NB1-A (Blood Derived Normal), aliquot ALCH-B3AX-NB1-A-1-0-D-A80C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f0c50bab-5f37-406b-8c4e-b2f0ec64ba6b

The open-access MAF lists 35 somatic variants for this specimen: 23 protein-altering or splice-affecting, 9 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 9, Intron 2, In Frame Del 2, Nonsense Mutation 1, Frame Shift Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BTBD18 | c.1666G>C p.E556Q | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as COSV104376712; called by muse, mutect2
- CHUK | c.1474G>A p.E492K | Missense Mutation (SNP) | VAF 16/244 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.283); catalogued as COSV64917539; called by muse, mutect2
- CKAP4 | c.226_231del p.G76_G77del | In Frame Del (DEL) | VAF 3/16 reads (19%) | catalogued as rs750145170; called by mutect2, varscan2
- DEAF1 | c.69_98del p.A24_A33del | In Frame Del (DEL) | VAF 9/37 reads (24%) | catalogued as rs754135731; called by mutect2, varscan2*
- HNRNPUL1 | c.677G>A p.R226Q | Missense Mutation (SNP) | VAF 32/186 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.09); catalogued as COSV54562476; called by muse, mutect2, varscan2
- RHOT2 | c.1040G>A p.R347H | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as rs904049264, COSV53466136; called by muse, varscan2
- SCTR | c.520C>T p.R174C | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773335176, COSV50032545; called by mutect2, varscan2
- ZP4 | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs755870661, COSV63913496; called by mutect2, varscan2
- B3GALT5 | c.742C>A p.L248I | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- C11orf95 | c.804C>G p.F268L | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- CAMSAP2 | c.2284G>A p.V762M (on ENST00000236925 / NM_001297707.2; = p.V751M on NM_203459.3) | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- CHUK | c.1285G>A p.E429K | Missense Mutation (SNP) | VAF 26/288 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2
- CROCC2 | c.3385G>C p.E1129Q | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); called by muse, mutect2
- DCUN1D4 | c.214G>T p.G72* | Nonsense Mutation (SNP) | VAF 11/167 reads (7%) | called by muse, mutect2
- DNAH17 | c.124G>C p.E42Q | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- DPYS | c.61G>C p.E21Q | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2
- EEF1AKMT3 | c.589C>T p.P197S | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); called by muse, mutect2
- HSPA9 | c.1534C>G p.P512A | Missense Mutation (SNP) | VAF 16/216 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.833); called by muse, mutect2
- KIAA0895L | c.925C>T p.R309W | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- MEPE | c.270C>G p.F90L | Missense Mutation (SNP) | VAF 15/146 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PCDHB16 | c.2318del p.N773Tfs*11 | Frame Shift Del (DEL) | VAF 5/39 reads (13%) | called by mutect2, pindel, varscan2
- SVEP1 | c.4840G>A p.G1614R | Missense Mutation (SNP) | VAF 7/158 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZFYVE9 | c.3720G>T p.Q1240H | Missense Mutation (SNP) | VAF 7/109 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2
- CHUK | c.1473G>A p.L491= | Silent (SNP) | VAF 16/244 reads (7%) | catalogued as rs779353891; called by muse, mutect2
- DST | c.5409G>A p.G1803= | Silent (SNP) | VAF 5/48 reads (10%) | catalogued as rs1257920489; called by muse, mutect2, varscan2
- GRB14 | c.1407G>A p.Q469= | Silent (SNP) | VAF 12/294 reads (4%) | called by muse, mutect2
- HRH3 | c.222C>G p.L74= | Silent (SNP) | VAF 7/71 reads (10%) | catalogued as COSV58048426, COSV58049172; called by muse, mutect2
- MORC4 | c.210G>A p.T70= | Silent (SNP) | VAF 11/144 reads (8%) | catalogued as rs896474913; called by muse, mutect2
- MTCH2 | c.42C>T p.L14= | Silent (SNP) | VAF 12/99 reads (12%) | catalogued as rs1182404518, COSV56768561; called by muse, mutect2
- NPR2 | c.1737C>T p.L579= | Silent (SNP) | VAF 16/291 reads (5%) | called by muse, mutect2
- PSG6 | c.573G>A p.R191= | Silent (SNP) | VAF 26/193 reads (13%) | catalogued as rs1058688, COSV51831805, COSV99414322; called by muse, mutect2, varscan2
- SYNE1 | c.23214C>T p.L7738= (on ENST00000367255 / NM_182961.4; = p.L7667= on NM_033071.3) | Silent (SNP) | VAF 17/119 reads (14%) | catalogued as rs543882781, COSV54896924; called by muse, mutect2, varscan2
- CPAMD8 | c.5567+279C>T | Intron (SNP) | VAF 3/19 reads (16%) | catalogued as rs1048890497, COSV50185373; called by muse, varscan2
- ODF2 | chr9:128456217 C>T | 5'Flank (SNP) | VAF 9/66 reads (14%) | called by muse, mutect2, varscan2
- PCMT1 | c.230-5463G>A | Intron (SNP) | VAF 11/106 reads (10%) | catalogued as rs774737947; called by muse, mutect2, varscan2
